Somatic mutation profile of tumor specimen TCGA-63-5131-01A (aliquot TCGA-63-5131-01A-01D-1441-08) from TCGA case TCGA-63-5131, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-5131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69b68177-0125-46f1-80e3-4b58d748f911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-63-5131-10A (Blood Derived Normal), aliquot TCGA-63-5131-10A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2aae75e-84f8-49b3-a465-683337acec7e

The open-access MAF lists 315 somatic variants for this specimen: 255 protein-altering or splice-affecting, 55 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 221, Silent 55, Nonsense Mutation 14, Splice Site 9, Frame Shift Del 6, Splice Region 3, Intron 3, Translation Start Site 1, 5'UTR 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 45/86 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52942963; called by muse, mutect2, varscan2
- ACAD10 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as rs759612346, COSV58153904; called by muse, mutect2, varscan2
- ACAD10 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs765259177, COSV58153707; called by muse, mutect2, varscan2
- ACO2 | c.502C>A p.P168T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53440971; called by muse, mutect2, varscan2
- ACSM3 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV55499810; called by muse, mutect2, varscan2
- ADAM2 | c.2197C>G p.P733A | Missense Mutation (SNP) | VAF 82/621 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55858791; called by muse, mutect2, varscan2
- ADAMTS12 | c.1834del p.D612Tfs*29 | Frame Shift Del (DEL) | VAF 56/301 reads (19%) | catalogued as COSV61277156; called by mutect2, pindel, varscan2
- ADAMTS9 | c.4414G>C p.D1472H | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.738); catalogued as COSV55775006; called by muse, mutect2, varscan2
- ADGRB3 | c.4531C>A p.L1511M | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV53234630; called by muse, mutect2, varscan2
- ADIPOR2 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 159/275 reads (58%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.484); catalogued as rs1395620999, COSV63945413; called by muse, mutect2, varscan2
- AGPS | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV51560912; called by muse, mutect2, varscan2
- AKAP11 | c.2447C>G p.S816C | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV50292554, COSV50297009; called by muse, mutect2, varscan2
- ALMS1 | c.5843G>T p.S1948I | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.786); catalogued as rs1300252739, COSV52502664; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD6 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV60228701; called by muse, mutect2, varscan2
- ASAP2 | c.1024-1G>A p.X342_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as COSV55627326, COSV99856198; called by muse, mutect2, varscan2
- ASIC1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57316081; called by muse, mutect2, varscan2
- ASIC4 | c.118del p.R40Efs*54 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as COSV61733250; called by mutect2, pindel, varscan2
- ASTL | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60903547; called by muse, mutect2, varscan2
- ATP11B | c.852-2A>G p.X284_splice | Splice Site (SNP) | VAF 12/220 reads (5%) | catalogued as COSV100017506; called by muse, mutect2
- BANK1 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV59838266; called by muse, mutect2, varscan2
- BANP | c.1112A>G p.Y371C (on ENST00000286122; = p.Y340C on NM_017869.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53733687; called by muse, mutect2, varscan2
- BYSL | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764063989, COSV57827754; called by muse, mutect2, varscan2
- C10orf120 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs770120675, COSV61491609; called by muse, mutect2, varscan2
- C16orf46 | c.726T>A p.D242E | Missense Mutation (SNP) | VAF 59/382 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV55150062; called by muse, mutect2, varscan2
- C1QTNF4 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV56782750, COSV56784654; called by muse, mutect2, varscan2
- C2orf16 | c.3159G>C p.Q1053H | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1558458167, COSV62673761, COSV62674937; called by muse, mutect2, varscan2
- C3orf18 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1290405532; called by muse, mutect2, varscan2
- C6orf118 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV57812484; called by muse, mutect2, varscan2
- C8orf33 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58895273; called by muse, mutect2, varscan2
- CACNA1I | c.3869C>A p.P1290Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV60800974, COSV60809917; called by muse, mutect2, varscan2
- CAMKK2 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 62/215 reads (29%) | catalogued as COSV61212859, COSV61214023; called by muse, mutect2, varscan2
- CCDC102B | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755743398, COSV60134490; called by muse, mutect2, varscan2
- CCDC88A | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55056255; called by muse, mutect2
- CD53 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV54760013; called by muse, mutect2, varscan2
- CDH2 | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.633); catalogued as COSV52271708, COSV52295813; called by muse, mutect2, varscan2
- CDH9 | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50252261; called by muse, mutect2, varscan2
- CDHR2 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56134621; called by muse, mutect2, varscan2
- CECR2 | c.3566A>T p.H1189L (on ENST00000342247 / NM_001290047.2; = p.H1005L on NM_001290046.1) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1351661471, COSV52836123; called by muse, mutect2, varscan2
- CEP162 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.087); catalogued as COSV57617486, COSV57622978; called by muse, mutect2, varscan2
- CEP192 | c.2132C>G p.S711C | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58059825; called by muse, mutect2, varscan2
- CERS3 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 49/113 reads (43%) | catalogued as COSV52564924; called by muse, mutect2, varscan2
- CFAP251 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55838851; called by muse, mutect2, varscan2
- CFAP47 | c.4918G>T p.A1640S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV57971301; called by muse, mutect2, varscan2
- CHD4 | c.2158G>T p.G720C (on ENST00000357008 / NM_001363606.2; = p.G733C on NM_001273.5) | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58894785, COSV58905665; called by muse, mutect2, varscan2
- CHEK2 | c.1340A>G p.Y447C (on ENST00000382580 / NM_001005735.2; = p.Y404C on NM_007194.4) | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060502707, COSV60415927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN6 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV63162042; called by muse, mutect2, varscan2
- COIL | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53593760; called by muse, mutect2, varscan2
- COL11A1 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV62172860; called by muse, mutect2, varscan2
- COL19A1 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs746993827, COSV59565340; called by muse, mutect2, varscan2
- COL5A3 | c.4058G>T p.R1353L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs771836964, COSV53406165, COSV53413860; called by muse, mutect2, varscan2
- COPG2 | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58404153; called by muse, mutect2, varscan2
- COX7B2 | c.43A>T p.I15F | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.346); catalogued as COSV57213512; called by muse, mutect2
- CPLX4 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV55312809; called by muse, mutect2, varscan2
- CPNE6 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53742506; called by muse, mutect2, varscan2
- CRACR2A | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 91/178 reads (51%) | catalogued as COSV52910214, COSV52913292; called by muse, mutect2, varscan2
- CRKL | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.857); catalogued as COSV62882741, COSV62883680; called by muse, mutect2, varscan2
- CSMD2 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 31/157 reads (20%) | catalogued as COSV53878982; called by muse, mutect2, varscan2
- CUTA | c.170C>T p.S57L (on ENST00000488034 / NM_001014840.2; = p.S34L on NM_015921.3) | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs762618918, COSV53378281; called by muse, mutect2, varscan2
- CXXC1 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1407733204, COSV53273139; called by muse, mutect2, varscan2
- CYP2C19 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64906775; called by muse, mutect2, varscan2
- DCAF12L1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV64421172; called by muse, mutect2, varscan2
- DENND2B | c.1096G>T p.G366* | Nonsense Mutation (SNP) | VAF 54/123 reads (44%) | catalogued as COSV58201137; called by muse, mutect2, varscan2
- DKK1 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.075); catalogued as rs761830028, COSV100906521, COSV64759956; called by muse, mutect2, varscan2
- DMD | c.7272G>T p.Q2424H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as COSV104414708, COSV58891525; called by muse, mutect2, varscan2
- DNAH7 | c.6047A>T p.Q2016L | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56751786; called by muse, mutect2, varscan2
- DNAH7 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV56751791, COSV56754965; called by muse, mutect2, varscan2
- DNAJC6 | c.754C>A p.R252S | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54769674, COSV54773489; called by muse, mutect2, varscan2
- DNM3 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV62453028; called by muse, mutect2, varscan2
- DPP10 | c.115C>A p.L39M | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as COSV59664570; called by muse, mutect2, varscan2
- DUS2 | c.313A>T p.N105Y | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV62707849; called by muse, mutect2, varscan2
- DYNLRB1 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV55963662; called by muse, mutect2, varscan2
- EPHB1 | c.1460A>T p.Q487L | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV67654037; called by muse, mutect2
- ERCC6 | c.956G>C p.R319T | Missense Mutation (SNP) | VAF 42/242 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100876111, COSV63387851; called by muse, mutect2, varscan2
- F2R | c.1066T>C p.C356R | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59928307; called by muse, mutect2, varscan2
- FAM90A1 | c.1082G>C p.R361P | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100274261, COSV56709974; called by muse, mutect2, varscan2
- FANCL | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1012663252, COSV52072640; called by muse, mutect2, varscan2
- FAT3 | c.3344G>C p.W1115S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53075506; called by muse, mutect2
- FBXL22 | c.374C>A p.P125Q | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV62216421; called by muse, mutect2, varscan2
- FGF6 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57403341; called by muse, mutect2, varscan2
- FLT3 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 191/298 reads (64%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV54043965; called by muse, mutect2, varscan2
- FSD1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV55694533; called by muse, mutect2, varscan2
- GABRB3 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54650381; called by muse, mutect2, varscan2
- GABRP | c.1310A>G p.Y437C | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54661320; called by muse, mutect2, varscan2
- GARRE1 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55096522; called by muse, mutect2, varscan2
- GATAD2B | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV64083158; called by muse, mutect2, varscan2
- GC | c.129G>T p.L43= | Splice Region (SNP) | VAF 25/77 reads (32%) | catalogued as rs769030498, COSV56735280; called by muse, mutect2, varscan2
- GC | c.129-1G>T p.X43_splice | Splice Site (SNP) | VAF 25/76 reads (33%) | catalogued as rs112961993, COSV56735294; called by muse, mutect2, varscan2
- GHITM | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64538236; called by muse, mutect2, varscan2
- GIMAP4 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV55431101; called by muse, mutect2, varscan2
- GPR158 | c.2284C>A p.P762T | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542611999, COSV66265358; called by muse, mutect2, varscan2
- GREB1 | c.5760C>G p.D1920E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.846); catalogued as COSV52180533, COSV52191810; called by muse, mutect2, varscan2
- GSTM5 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 104/399 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56656534; called by muse, mutect2, varscan2
- GTPBP1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199570933, COSV99322921; called by muse, mutect2
- GYPE | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs763843605, COSV62261401; called by muse, mutect2, varscan2
- HECTD1 | c.3868G>C p.D1290H | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67945075; called by muse, mutect2, varscan2
- HELZ2 | c.5161C>T p.Q1721* (on ENST00000467148 / NM_001037335.2; = p.Q1152* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV101427524, COSV71295381; called by muse, mutect2, varscan2
- HLF | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV56828534; called by muse, mutect2, varscan2
- HNRNPC | c.528G>C p.K176N (on ENST00000420743; = p.K163N on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV60143742; called by muse, mutect2, varscan2
- HRH1 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV67955013; called by muse, mutect2, varscan2
- HSP90AB1 | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1251979456, COSV51487561; called by muse, mutect2, varscan2
- HSPA4L | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); catalogued as COSV56543619; called by muse, mutect2, varscan2
- HSPB8 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.084); catalogued as COSV56136872, COSV56137127, COSV56137340; called by muse, mutect2, varscan2
- IGF2R | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63626353; called by muse, mutect2, varscan2
- INTS3 | c.2929G>A p.E977K | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV55162069; called by muse, mutect2, varscan2
- ITFG1 | c.241A>G p.N81D | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV54514297; called by muse, mutect2, varscan2
- ITGA8 | c.1810T>G p.L604V | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65224570; called by muse, mutect2, varscan2
- ITPRID2 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57469514, COSV57473962; called by muse, mutect2, varscan2
- JARID2 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs1473935768, COSV59185269; called by muse, mutect2, varscan2
- KCNA4 | c.987G>T p.L329F | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV60250695; called by muse, mutect2, varscan2
- KCNA5 | c.1207C>G p.R403G | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52903705, COSV99363617; called by muse, mutect2, varscan2
- KCNH1 | c.594C>G p.Y198* | Nonsense Mutation (SNP) | VAF 35/164 reads (21%) | catalogued as COSV55069691; called by muse, mutect2, varscan2
- KCNH5 | c.104T>A p.I35N | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59752150; called by muse, mutect2, varscan2
- KIF13B | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV73054157; called by muse, mutect2, varscan2
- KIF18A | c.1741A>G p.R581G | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV54180993; called by muse, mutect2, varscan2
- KIF21A | c.1439A>C p.H480P | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100735281; called by muse, mutect2
- KLHL40 | c.1262A>T p.E421V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV55132796; called by muse, mutect2, varscan2
- KLHL41 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.788); catalogued as COSV52929435; called by muse, mutect2, varscan2
- LPA | c.4470A>T p.Q1490H | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as COSV60296518; called by muse, mutect2, varscan2
- LRP1B | c.13073T>G p.V4358G | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV67186289; called by muse, mutect2, varscan2
- LRP1B | c.10277A>T p.E3426V | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV67186299; called by muse, mutect2
- LRPAP1 | c.417T>A p.S139R | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV56345607; called by muse, mutect2, varscan2
- LRRTM3 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63661473; called by muse, mutect2, varscan2
- LZTR1 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as rs780217270, COSV53145117; called by muse, mutect2, varscan2
- MAGEC1 | c.1496del p.P499Lfs*131 | Frame Shift Del (DEL) | VAF 119/221 reads (54%) | catalogued as COSV53581588, COSV99596773; called by mutect2, pindel, varscan2
- MAGEE1 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as COSV63908864; called by muse, mutect2, varscan2
- MANBAL | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.144); catalogued as COSV65311378, COSV65311428; called by muse, mutect2, varscan2
- MAP2K1 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 70/141 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.226); catalogued as COSV61068593; called by muse, varscan2
- MAP3K19 | c.715C>G p.P239A | Missense Mutation (SNP) | VAF 110/324 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV59636584; called by muse, mutect2
- MED17 | c.1106A>G p.Y369C | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52599356; called by muse, mutect2, varscan2
- MLH3 | c.2599G>C p.E867Q | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV53152202; called by muse, mutect2, varscan2
- MRPL1 | c.801A>G p.I267M | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV59673222; called by muse, mutect2, varscan2
- MTARC1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144056103; called by muse, mutect2, varscan2
- MTERF3 | c.1060-1G>T p.X354_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99748956; called by muse, mutect2
- MTNR1B | c.1064T>A p.V355E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs1291032022, COSV57065337; called by muse, mutect2, varscan2
- MTRF1L | c.469G>C p.A157P | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65873126; called by muse, mutect2, varscan2
- MYH3 | c.658C>G p.Q220E | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV56860882; called by muse, mutect2, varscan2
- MYH6 | c.1793dup p.N598Kfs*38 | Frame Shift Ins (INS) | VAF 40/112 reads (36%) | catalogued as rs774500922; called by mutect2, varscan2
- MYOM3 | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); catalogued as COSV58389605; called by muse, mutect2, varscan2
- MYT1 | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV60500964; called by muse, mutect2, varscan2
- NAA35 | c.1922C>G p.S641C | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV64484006; called by muse, mutect2, varscan2
- NALCN | c.1768C>A p.L590I | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as CM151794, COSV51917750; called by muse, mutect2, varscan2
- NAV1 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV55214033; called by muse, mutect2, varscan2
- NCR1 | c.682+1G>T p.X228_splice | Splice Site (SNP) | VAF 125/261 reads (48%) | catalogued as COSV52555341, COSV99400689; called by muse, mutect2, varscan2
- NDN | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV59358413, COSV59358508; called by muse, mutect2, varscan2
- NDN | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59358422; called by muse, mutect2, varscan2
- NFATC3 | c.2301G>T p.L767F | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.386); catalogued as COSV60470876; called by muse, mutect2, varscan2
- NMI | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as COSV54637433; called by muse, mutect2, varscan2
- NOTUM | c.696C>A p.S232R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV68825737, COSV68826000; called by muse, mutect2, varscan2
- NUP210L | c.5260G>A p.V1754I | Missense Mutation (SNP) | VAF 84/254 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55141525; called by muse, mutect2, varscan2
- OR10P1 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59006695; called by muse, mutect2, varscan2
- OR14K1 | c.892G>C p.A298P | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs756876496, COSV51720929, COSV99314962; called by muse, mutect2, varscan2
- OR1S2 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.438); catalogued as COSV56918371; called by muse, mutect2, varscan2
- OR2M2 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 46/514 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV62897771; called by muse, mutect2
- OR4A5 | c.95C>A p.T32K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV60521484; called by muse, mutect2, varscan2
- OR4D5 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58305600; called by muse, mutect2, varscan2
- OR52A5 | c.443T>G p.L148R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV56614190; called by muse, mutect2, varscan2
- OR5A2 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as COSV57390389; called by muse, mutect2, varscan2
- OR5AP2 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57256902; called by muse, mutect2, varscan2
- OR5K4 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 377/590 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100721295; called by muse, mutect2, varscan2
- OR5M11 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1225026225, COSV101602048, COSV73141630; called by muse, mutect2, varscan2
- OR8H3 | c.187T>G p.F63V | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57907444; called by muse, mutect2
- OSMR | c.2214C>T p.S738= | Splice Region (SNP) | VAF 52/335 reads (16%) | catalogued as COSV57080967; called by muse, mutect2, varscan2
- PAGE2B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 93/131 reads (71%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV66611070; called by muse, mutect2, varscan2
- PCDH11X | c.1324G>C p.G442R | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53442685, COSV53490194; called by muse, mutect2, varscan2
- PCNX1 | c.5437A>T p.S1813C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.662); catalogued as COSV53089172; called by muse, mutect2, varscan2
- PDZRN4 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68400622, COSV68404292; called by muse, mutect2, varscan2
- PFAS | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV58978400; called by muse, mutect2, varscan2
- PGM5 | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV67166824; called by muse, mutect2, varscan2
- PLA2G2A | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1320028577, COSV64286852; called by muse, mutect2, varscan2
- PLXND1 | c.2051C>G p.S684C | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV100139037, COSV60719375; called by muse, mutect2
- POTEH | c.367C>G p.H123D | Missense Mutation (SNP) | VAF 123/989 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV58879759; called by muse, varscan2
- PPP1R13B | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 30/136 reads (22%) | catalogued as COSV52448613, COSV52452895; called by muse, mutect2, varscan2
- PRELP | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58114817; called by muse, mutect2, varscan2
- PRKAR1B | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV64317758; called by muse, mutect2, varscan2
- PRMT7 | c.794G>T p.R265M | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV59832133; called by muse, mutect2
- PRMT7 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs751037036, COSV59832139; called by muse, mutect2
- PTGFR | c.908T>A p.V303E | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66114329; called by muse, mutect2, varscan2
- RADIL | c.1961A>G p.D654G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67650811; called by muse, mutect2, varscan2
- RASL11A | c.543C>G p.N181K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV54079626; called by muse, mutect2, varscan2
- RGP1 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779533411, COSV65238831; called by muse, mutect2, varscan2
- RGS7 | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100464618, COSV100464694; called by muse, mutect2
- RIMS3 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); catalogued as COSV65503867; called by muse, mutect2, varscan2
- RNF138 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV55233265; called by muse, mutect2, varscan2
- ROBO1 | c.2448G>T p.W816C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71391658; called by muse, mutect2, varscan2
- ROBO1 | c.2447G>C p.W816S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71391663; called by muse, mutect2, varscan2
- ROBO2 | c.1396A>G p.T466A | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs779487034, COSV59896755; called by muse, mutect2, varscan2
- ROBO3 | c.3762G>T p.K1254N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs1161082812, COSV60621432; called by muse, mutect2, varscan2
- RPRD2 | c.1681A>C p.T561P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as rs1463928206, COSV64818657; called by muse, mutect2, varscan2
- RXFP3 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 57/261 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV57504040; called by muse, mutect2, varscan2
- RYR1 | c.4426G>T p.G1476W | Missense Mutation (SNP) | VAF 29/378 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62088785; called by muse, mutect2
- RYR2 | c.5393C>A p.A1798D | Missense Mutation (SNP) | VAF 128/418 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV63657841, COSV63661822; called by muse, mutect2, varscan2
- SALL1 | c.2804C>G p.T935R | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as rs755926434, COSV51753209, COSV51761394; called by muse, mutect2, varscan2
- SARS1 | c.1257G>A p.K419= | Splice Region (SNP) | VAF 17/99 reads (17%) | catalogued as COSV52319515; called by muse, mutect2, varscan2
- SCN10A | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV71860239, COSV71862644; called by muse, mutect2, varscan2
- SCRIB | c.2663G>T p.G888V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57582186; called by muse, varscan2
- SDK1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV67354921; called by muse, mutect2, varscan2
- SEPTIN10 | c.87T>G p.D29E | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61779284; called by muse, mutect2, varscan2
- SETBP1 | c.3599T>C p.V1200A | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.02); catalogued as COSV56312961; called by muse, mutect2, varscan2
- SIL1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54527890; called by muse, mutect2, varscan2
- SLC27A6 | c.1679T>G p.I560S | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52479335; called by muse, mutect2, varscan2
- SLC2A1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 69/164 reads (42%) | catalogued as COSV65286709; called by muse, mutect2, varscan2
- SLC35F4 | c.259C>T p.P87S (on ENST00000339762 / NM_001352015.2; = p.P51S on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as COSV60262745; called by muse, mutect2, varscan2
- SLC4A8 | c.608A>T p.D203V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV60647665; called by muse, mutect2, varscan2
- SLC7A13 | c.794C>G p.T265R | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52532444; called by muse, mutect2, varscan2
- SNRPB | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 119/321 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs1353147727, COSV60014953, COSV60015414; called by muse, mutect2, varscan2
- STARD13 | c.2888C>A p.P963H (on ENST00000336934 / NM_001243476.3; = p.P845H on NM_052851.3) | Missense Mutation (SNP) | VAF 70/117 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261673521, COSV55227141; called by muse, mutect2, varscan2
- TACR1 | c.178C>G p.H60D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59479234; called by muse, mutect2, varscan2
- TACR3 | c.738-1G>C p.X246_splice | Splice Site (SNP) | VAF 26/126 reads (21%) | catalogued as CS102669, COSV59197900; called by muse, mutect2, varscan2
- TANC2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV67330140; called by muse, mutect2, varscan2
- THEMIS | c.125G>T p.C42F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64069245; called by muse, mutect2, varscan2
- TIA1 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV57005692; called by muse, mutect2, varscan2
- TNPO2 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV63507514; called by muse, mutect2, varscan2
- TNS2 | c.646G>C p.E216Q (on ENST00000314250 / NM_170754.4; = p.E226Q on NM_015319.2) | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757232422, COSV58574715; called by muse, mutect2, varscan2
- TOP1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.614); catalogued as rs778237366, COSV63692885; called by muse, mutect2, varscan2
- TPO | c.2406C>A p.D802E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as COSV61094587, COSV61102965; called by muse, mutect2, varscan2
- TRIM8 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56659504, COSV56661927; called by muse, mutect2
- TSC2 | c.600-1G>T p.X200_splice | Splice Site (SNP) | VAF 22/58 reads (38%) | catalogued as CS992719, COSV54756054, COSV99552886; called by muse, mutect2, varscan2
- TSHZ1 | c.2015C>A p.P672H (on ENST00000580243 / NM_001308210.2; = p.P627H on NM_005786.6) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368032787, COSV59005448; called by muse, mutect2, varscan2
- TTK | c.35C>G p.T12R | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.005); catalogued as COSV57881483; called by muse, mutect2, varscan2
- TTLL1 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs116153895, COSV56737799; called by muse, mutect2
- TTN | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 23/82 reads (28%) | PolyPhen benign (0.083); catalogued as COSV59886738, COSV60027269; called by muse, mutect2, varscan2
- TUBA1C | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | catalogued as rs1376721420, COSV56509311; called by muse, mutect2, varscan2
- TUBGCP6 | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1413036847, COSV50536525; called by muse, mutect2, varscan2
- UBN2 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56027618, COSV99944230; called by muse, mutect2, varscan2
- UGT2B11 | c.1254C>G p.N418K | Missense Mutation (SNP) | VAF 86/391 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV71422971; called by muse, mutect2, varscan2
- ULBP2 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs772380793, COSV66265481; called by muse, mutect2, varscan2
- UNC5D | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54769694; called by muse, mutect2, varscan2
- UNC79 | c.3596A>T p.N1199I (on ENST00000393151 / NM_001346218.2; = p.N1022I on NM_020818.5) | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56373761; called by muse, mutect2, varscan2
- UTP25 | c.1164C>A p.N388K | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV71965726; called by muse, mutect2, varscan2
- WNK4 | c.1171-1G>C p.X391_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55901452; called by muse, mutect2, varscan2
- XPNPEP2 | c.1107+1G>A p.X369_splice | Splice Site (SNP) | VAF 79/111 reads (71%) | catalogued as rs759911544, COSV64368424; called by muse, mutect2, varscan2
- ZBTB16 | c.196A>G p.N66D | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.061); catalogued as rs1458297420, COSV60089191; called by muse, mutect2, varscan2
- ZBTB44 | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV63536713; called by muse, mutect2, varscan2
- ZBTB46 | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55506749; called by muse, mutect2, varscan2
- ZC3H13 | c.2462A>T p.K821I | Missense Mutation (SNP) | VAF 198/307 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV54447637; called by muse, mutect2, varscan2
- ZFP36L2 | c.482C>G p.P161R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV56697049; called by muse, mutect2, varscan2
- ZNF131 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV61001124; called by muse, mutect2, varscan2
- ZNF208 | c.3151C>A p.H1051N | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV68100509; called by muse, mutect2, varscan2
- ZNF33B | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV63941840; called by muse, mutect2, varscan2
- ZNF486 | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58717382; called by muse, mutect2, varscan2
- ZNF519 | c.73C>G p.Q25E | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV73913158; called by muse, mutect2, varscan2
- ZNF623 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 38/268 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs766721710, COSV71697082; called by muse, mutect2, varscan2
- ZNF675 | c.838G>C p.G280R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.851); catalogued as COSV63094923; called by muse, mutect2, varscan2
- ZNF676 | c.592G>A p.E198K (on ENST00000650058; = p.E166K on NM_001001411.3) | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as rs1476174600, COSV68092153; called by muse, mutect2, varscan2
- ZNF687 | c.1459G>C p.G487R | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55014957; called by muse, mutect2, varscan2
- AATF | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- GPR132 | c.347del p.K116Rfs*2 | Frame Shift Del (DEL) | VAF 47/286 reads (16%) | called by mutect2, pindel, varscan2
- GREB1 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GSE1 | c.341del p.G114Afs*11 | Frame Shift Del (DEL) | VAF 66/175 reads (38%) | called by mutect2, pindel, varscan2
- IGHM | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 23/58 reads (40%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- LYST | c.4868del p.P1623Lfs*25 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- MRC1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- PRAMEF15 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 146/453 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADGRV1 | c.11829G>T p.R3943= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV67978460; called by muse, mutect2, varscan2
- ALDH6A1 | c.249T>A p.I83= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV63245763, COSV63246394; called by muse, mutect2, varscan2
- ATP10D | c.2070T>G p.A690= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV56703796; called by muse, mutect2, varscan2
- CDC42BPB | c.4044G>A p.V1348= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as COSV63473863, COSV63475807; called by muse, mutect2, varscan2
- CDH19 | c.1368G>A p.L456= | Silent (SNP) | VAF 34/206 reads (17%) | catalogued as rs751706222, COSV50954386; called by muse, mutect2, varscan2
- CNTNAP2 | c.1032C>A p.G344= | Silent (SNP) | VAF 101/306 reads (33%) | catalogued as COSV62145397; called by muse, mutect2, varscan2
- COL2A1 | c.1452C>T p.P484= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs755093756, COSV61527781; ClinVar: likely benign; called by muse, varscan2
- COL4A1 | c.1080A>T p.P360= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV65421362; called by muse, mutect2, varscan2
- COL4A4 | c.2325T>C p.L775= | Silent (SNP) | VAF 87/247 reads (35%) | catalogued as COSV61629524; called by muse, mutect2, varscan2
- DDX1 | c.1623A>T p.S541= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as COSV51837963; called by muse, mutect2, varscan2
- EIF2B2 | c.534C>G p.L178= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as COSV56719827; called by muse, mutect2, varscan2
- ESYT1 | c.255C>T p.L85= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs80169445, COSV57271572, COSV57276066; called by muse, mutect2, varscan2
- FRAS1 | c.4110A>G p.T1370= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV53589005; called by muse, mutect2, varscan2
- FRAS1 | c.9102C>A p.S3034= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV53589028; called by muse, mutect2, varscan2
- ITPKB | c.969C>T p.L323= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV55257189; called by muse, mutect2, varscan2
- KCNH8 | c.216G>T p.G72= | Silent (SNP) | VAF 124/236 reads (53%) | catalogued as COSV60456503; called by muse, mutect2, varscan2
- KLHL1 | c.171C>G p.L57= | Silent (SNP) | VAF 51/90 reads (57%) | catalogued as COSV64766964, COSV64777483; called by muse, mutect2, varscan2
- KLHL40 | c.855G>A p.K285= | Silent (SNP) | VAF 105/228 reads (46%) | catalogued as COSV55132786; called by muse, mutect2, varscan2
- KRT40 | c.351G>A p.L117= | Silent (SNP) | VAF 13/321 reads (4%) | catalogued as COSV100898777; called by muse, mutect2
- LRP1B | c.12645T>C p.D4215= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs1201073437, COSV67186294; called by muse, mutect2, varscan2
- LRP5 | c.4095C>T p.S1365= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as rs199576767; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAM | c.4515G>T p.G1505= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV72073611; called by muse, mutect2, varscan2
- MKRN3 | c.726G>T p.R242= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV58808551; called by muse, mutect2, varscan2
- MYH4 | c.4422C>A p.S1474= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV55112221; called by muse, varscan2
- MYH6 | c.4780C>A p.R1594= | Silent (SNP) | VAF 44/295 reads (15%) | catalogued as COSV62447886, COSV62447912; called by muse, mutect2, varscan2
- NLGN1 | c.1002A>G p.L334= | Silent (SNP) | VAF 42/620 reads (7%) | catalogued as rs367555290; called by muse, mutect2
- OBSCN | c.17901C>T p.R5967= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs749964634, COSV52739640; called by muse, mutect2, varscan2
- OR2A5 | c.504C>T p.F168= | Silent (SNP) | VAF 107/400 reads (27%) | catalogued as COSV68738505; called by muse, mutect2, varscan2
- OR4A15 | c.409C>A p.R137= | Silent (SNP) | VAF 86/382 reads (23%) | catalogued as COSV59033588, COSV59035787; called by muse, mutect2
- OR4F21 | c.198C>G p.L66= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- OR51A4 | c.12C>A p.I4= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as COSV66749037, COSV66750190; called by muse, mutect2, varscan2
- OR56A4 | c.393C>G p.T131= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV100417470, COSV58109197; called by muse, mutect2, varscan2
- OR8B2 | c.861C>T p.L287= | Silent (SNP) | VAF 88/234 reads (38%) | catalogued as COSV66664159; called by muse, mutect2, varscan2
- PAPOLB | c.423G>A p.Q141= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs749219869, COSV68199144; called by muse, mutect2, varscan2
- PCDHA5 | c.456G>A p.P152= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV65349311; called by muse, mutect2, varscan2
- PIK3R5 | c.699C>A p.T233= | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV52650504; called by muse, mutect2, varscan2
- PM20D1 | c.1260C>T p.F420= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as COSV65648408; called by muse, mutect2, varscan2
- PPRC1 | c.525A>G p.P175= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV53383015; called by muse, mutect2, varscan2
- PTCHD4 | c.1579C>T p.L527= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59777617, COSV59798042; called by muse, mutect2, varscan2
- RAB40B | c.255G>T p.R85= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs1280165732, COSV53915056; called by muse, mutect2, varscan2
- RELN | c.4836C>T p.G1612= | Silent (SNP) | VAF 64/185 reads (35%) | catalogued as COSV58985737; called by muse, mutect2, varscan2
- SPACA1 | c.444A>G p.K148= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV52758983; called by muse, mutect2, varscan2
- SPTA1 | c.5737C>T p.L1913= | Silent (SNP) | VAF 98/292 reads (34%) | catalogued as COSV63748922, COSV63758521; called by muse, mutect2, varscan2
- ST3GAL4 | c.570A>C p.V190= (on ENST00000392669 / NM_001254758.1; = p.V186= on NM_006278.3) | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as COSV57105902; called by muse, mutect2, varscan2
- STAB1 | c.1344G>T p.G448= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV58732099; called by muse, mutect2, varscan2
- TMEM132D | c.99C>A p.I33= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV101399808, COSV70625289; called by muse, mutect2
- TMEM72 | c.813C>T p.A271= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV67460135, COSV67460486; called by muse, mutect2, varscan2
- TMX4 | c.453C>A p.S151= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV55679722; called by muse, mutect2, varscan2
- UBALD2 | c.57G>A p.L19= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV59499023; called by muse, mutect2, varscan2
- UGT3A2 | c.426G>A p.V142= | Silent (SNP) | VAF 21/233 reads (9%) | catalogued as COSV56928387; called by muse, mutect2
- WDR81 | c.5220G>A p.V1740= (on ENST00000409644 / NM_001163809.2; = p.V689= on NM_152348.4) | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as rs1228652758, COSV100488523; called by muse, mutect2
- ZFAT | c.3321G>T p.A1107= | Silent (SNP) | VAF 79/470 reads (17%) | catalogued as COSV64734256; called by muse, mutect2, varscan2
- ZNF574 | c.2178A>G p.T726= | Silent (SNP) | VAF 63/128 reads (49%) | catalogued as COSV55901507; called by muse, mutect2, varscan2
- ZNF639 | c.789A>G p.K263= | Silent (SNP) | VAF 99/313 reads (32%) | catalogued as COSV58382708; called by muse, mutect2, varscan2
- ZNF763 | c.651C>T p.I217= (on ENST00000358987 / NM_001367172.2; = p.I220= on NM_001012753.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV59687086; called by muse, mutect2
- AC116366.2 | c.-638+11029C>T | Intron (SNP) | VAF 30/69 reads (43%) | catalogued as rs1274158976, COSV61818990; called by muse, mutect2, varscan2
- BCL9 | c.-2C>G | 5'UTR (SNP) | VAF 35/116 reads (30%) | catalogued as COSV52340924; called by muse, mutect2, varscan2
- RBMS1 | c.901-903C>G | Intron (SNP) | VAF 37/166 reads (22%) | catalogued as COSV100816692; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23978C>T | Intron (SNP) | VAF 97/275 reads (35%) | catalogued as rs769477177, COSV67440324, COSV67440610; called by muse, mutect2, varscan2
- XIRP2 | c.*843A>G | 3'UTR (SNP) | VAF 32/94 reads (34%) | catalogued as COSV54711222; called by muse, mutect2, varscan2
